Gene-level copy-number profile of tumor specimen HTMCP-02-01-01250-01A from CGCI case HTMCP-02-01-01250, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I.
Specimen HTMCP-02-01-01250-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 33b905cb-0af7-4d30-be51-b4a334f108d1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-01-01250-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/2efc0dae-30f2-443d-817f-a00d5670c8f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 953; copy number 2: 55,957; copy number 3: 1,495; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
